Somatic mutation profile of tumor specimen MMRF_2129_1_BM_CD138pos (aliquot MMRF_2129_1_BM_CD138pos_T1_KHS5U_L08130) from MMRF case MMRF_2129, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.6 years (22,865 days).
Specimen MMRF_2129_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c050e69-86cf-47b2-a813-5830a631ecf9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2129_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2129_1_PB_Whole_C2_KHS5U_L08131; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8776f0f5-5f94-4d7b-83a3-aa202fc55dfb

The open-access MAF lists 106 somatic variants for this specimen: 55 protein-altering or splice-affecting, 17 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 17, 3'UTR 16, Intron 7, Nonsense Mutation 4, 5'UTR 4, 3'Flank 3, Frame Shift Del 3, 5'Flank 2, RNA 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTL6B | c.550G>A p.V184I | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.871); catalogued as rs1431929583, COSV99355685; called by muse, mutect2
- BAZ2B | c.2591G>A p.R864H | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs202015347; called by muse, mutect2, varscan2
- EXT1 | c.2221C>T p.R741* | Nonsense Mutation (SNP) | VAF 108/232 reads (47%) | catalogued as COSV65484530; called by muse, mutect2, varscan2
- IGHV1-69 | c.109G>A p.V37M | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); catalogued as rs150196675; called by mutect2, varscan2
- IGHV2-70 | c.143T>G p.L48R | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as rs368172828; called by muse, varscan2
- IGHV2-70 | c.70A>G p.R24G | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs554527111; called by muse, varscan2
- IGHV2-70D | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1169792576; called by muse, varscan2
- IGLV3-1 | c.311A>G p.Y104C | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as rs142180628; called by muse, mutect2, varscan2
- KALRN | c.4633G>A p.A1545T | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs774429172; called by muse, mutect2, varscan2
- KIF16B | c.3478C>G p.Q1160E | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.276); catalogued as COSV61700672; called by muse, mutect2, varscan2
- MSH2 | c.2699C>A p.S900* | Nonsense Mutation (SNP) | VAF 5/57 reads (9%) | catalogued as CM1410387; called by muse, mutect2
- NIBAN2 | c.1477C>T p.R493W | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV55940876; called by muse, mutect2, varscan2
- OR8U1 | c.719C>T p.T240M | Missense Mutation (SNP) | VAF 63/129 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs541503390, COSV56414090; called by muse, mutect2, varscan2
- PCDHB3 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.062); catalogued as rs553356982, COSV99165541; called by muse, mutect2, varscan2
- RPL10 | c.208A>C p.I70L | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV50010499; called by muse, mutect2, varscan2
- SMARCA1 | c.548T>C p.L183P | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV64413429; called by muse, mutect2, varscan2
- SRPK3 | c.1312G>A p.A438T | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs781935040, COSV54207779; called by muse, mutect2, varscan2
- ST6GAL2 | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 4/56 reads (7%) | PolyPhen probably damaging (0.988); catalogued as COSV64527367; called by muse, mutect2
- STXBP5L | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV99874951; called by muse, mutect2
- SZT2 | c.3904C>T p.R1302W (on ENST00000634258 / NM_001365999.1; = p.R1245W on NM_015284.4) | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs541175680; called by muse, mutect2, varscan2
- TACC2 | c.6226G>A p.V2076I (on ENST00000334433; = p.V154I on NM_006997.4) | Missense Mutation (SNP) | VAF 154/411 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as rs199696107; called by muse, varscan2
- TJP1 | c.2051G>A p.R684H | Missense Mutation (SNP) | VAF 59/99 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1217741949; called by muse, mutect2, varscan2
- ZG16 | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 7/64 reads (11%) | catalogued as rs1389686158; called by muse, mutect2, varscan2
- C2CD2L | c.941T>G p.L314R | Missense Mutation (SNP) | VAF 77/375 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CCND1 | c.134T>C p.F45S | Missense Mutation (SNP) | VAF 106/166 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, varscan2
- CNTROB | c.564T>G p.D188E | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GCNA | c.1969A>G p.T657A | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2
- GPR33 | c.536G>A p.C179Y | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GPSM1 | c.1769G>A p.G590D | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.511); called by muse, mutect2
- GRID1 | c.2618T>G p.L873W | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- GRIN3A | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- IGHV1-69D | c.337T>A p.Y113N | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- IGHV2-70D | c.329A>G p.D110G | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, varscan2
- IGHV2-70D | c.169T>A p.W57R | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, varscan2
- IGHV2-70D | c.56C>G p.S19C | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGKV4-1 | c.72G>C p.M24I | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT deleterious (0.04); PolyPhen benign (0.091); called by muse, varscan2
- KAZN | c.1408G>T p.E470* | Nonsense Mutation (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
- KCNN2 | c.730T>C p.S244P (on ENST00000264773; = p.S456P on NM_021614.4) | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- MDK | c.243A>G p.G81= | Splice Region (SNP) | VAF 37/73 reads (51%) | called by muse, mutect2, varscan2
- NFIA | c.55C>G p.L19V | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- NFKB2 | c.459del p.K153Nfs*29 | Frame Shift Del (DEL) | VAF 18/106 reads (17%) | called by mutect2, pindel, varscan2
- OR5B3 | c.412G>C p.V138L | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.042); called by muse, mutect2
- PKHD1 | c.5639G>A p.S1880N | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PTPRZ1 | c.5810T>G p.V1937G | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- SHANK1 | c.704T>C p.L235P | Missense Mutation (SNP) | VAF 44/72 reads (61%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- SPATS2L | c.1636G>A p.A546T | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, mutect2
- SYNE4 | c.548_558del p.L183Pfs*54 | Frame Shift Del (DEL) | VAF 10/98 reads (10%) | called by mutect2, pindel
- TBL1X | c.467A>G p.Q156R | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.101); called by muse, varscan2
- TMEM132B | c.520T>G p.C174G | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTC6 | c.2130A>T p.K710N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.02); called by muse, mutect2
- TTLL5 | c.2601T>C p.S867= | Splice Region (SNP) | VAF 30/85 reads (35%) | called by muse, mutect2, varscan2
- UBR5 | c.1351_1352del p.L451Kfs*6 | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | called by mutect2, pindel
- VEPH1 | c.830A>G p.K277R | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2
- VWA5B1 | c.2024C>T p.A675V | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ZNF679 | c.508A>G p.N170D | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); called by muse, mutect2
- ABCG1 | c.1731C>T p.L577= | Silent (SNP) | VAF 30/59 reads (51%) | called by muse, mutect2, varscan2
- CCDC168 | c.2847T>C p.S949= | Silent (SNP) | VAF 16/368 reads (4%) | called by muse, mutect2
- FCGBP | c.2565C>A p.G855= | Silent (SNP) | VAF 106/164 reads (65%) | called by muse, mutect2, varscan2
- FGD5 | c.1590C>G p.P530= | Silent (SNP) | VAF 51/107 reads (48%) | catalogued as rs1399015617; called by muse, mutect2, varscan2
- GABRE | c.1467A>T p.P489= | Silent (SNP) | VAF 113/254 reads (44%) | catalogued as COSV64821017; called by muse, mutect2, varscan2
- HPS1 | c.147C>T p.T49= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as rs1318989724; called by muse, mutect2, varscan2
- IGHV1-69D | c.129T>C p.A43= | Silent (SNP) | VAF 10/28 reads (36%) | called by mutect2, varscan2
- IGHV2-70 | c.129C>T p.F43= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as rs548066677; called by muse, varscan2
- IGHV2-70D | c.354G>A p.R118= | Silent (SNP) | VAF 12/27 reads (44%) | called by muse, varscan2
- IGHV2-70D | c.297G>A p.V99= | Silent (SNP) | VAF 18/48 reads (38%) | called by muse, varscan2
- IGHV2-70D | c.168C>T p.S56= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as rs1233195687; called by muse, varscan2
- IGHV2-70D | c.57C>T p.S19= | Silent (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- LTB | c.252C>T p.S84= | Silent (SNP) | VAF 99/188 reads (53%) | catalogued as rs4647186, COSV65815060; called by muse, mutect2, varscan2
- PCDHA12 | c.1446G>A p.A482= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as COSV100250542; called by muse, mutect2, varscan2
- TOP2A | c.1332C>T p.A444= | Silent (SNP) | VAF 25/68 reads (37%) | called by muse, mutect2, varscan2
- WEE2 | c.897T>G p.A299= | Silent (SNP) | VAF 37/82 reads (45%) | called by muse, mutect2, varscan2
- ZNF516 | c.1821G>A p.P607= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as rs533522002, COSV71587636; called by muse, mutect2, varscan2
- ADAM22 | chr7:88201487 C>A | 3'Flank (SNP) | VAF 23/73 reads (32%) | called by muse, mutect2, varscan2
- AMZ1 | c.*1698G>C | 3'UTR (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- ASB17 | c.-53A>T | 5'UTR (SNP) | VAF 100/216 reads (46%) | called by muse, mutect2, varscan2
- CAMK2D | chr4:113761260 G>A | 5'Flank (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2, varscan2
- CASP14 | c.*174C>A | 3'UTR (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2
- CCND1 | c.-22C>G | 5'UTR (SNP) | VAF 20/29 reads (69%) | called by muse, mutect2, varscan2
- CCNI | c.-264C>A | 5'UTR (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- CD2AP | c.*567G>A | 3'UTR (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2
- CHRNA4 | c.*2182C>A | 3'UTR (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
- CSF2RA | c.*44G>A | 3'UTR (SNP) | VAF 18/264 reads (7%) | catalogued as rs781308302, COSV100817592; called by muse, mutect2
- GID4 | c.*2358del | 3'UTR (DEL) | VAF 24/58 reads (41%) | called by mutect2, pindel, varscan2
- GPR150 | c.*294T>A | 3'UTR (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- GREM2 | c.*3184G>A | 3'UTR (SNP) | VAF 20/63 reads (32%) | called by muse, mutect2, varscan2
- HAS3 | c.*2057T>C | 3'UTR (SNP) | VAF 30/60 reads (50%) | called by muse, mutect2, varscan2
- HLA-DPA1 | c.628+41C>G | Intron (SNP) | VAF 19/35 reads (54%) | called by muse, mutect2, varscan2
- HNRNPH2 | c.*594C>T | 3'UTR (SNP) | VAF 34/85 reads (40%) | called by muse, mutect2, varscan2
- IGKV3-20 | c.-3A>G | 5'UTR (SNP) | VAF 10/23 reads (43%) | catalogued as rs539189594; called by muse, varscan2
- IKZF3 | c.*3345C>T | 3'UTR (SNP) | VAF 8/34 reads (24%) | called by mutect2, varscan2
- KIF20B | c.*289A>T | 3'UTR (SNP) | VAF 20/47 reads (43%) | called by muse, mutect2, varscan2
- MAP4K4 | chr2:101697990 G>A | 5'Flank (SNP) | VAF 52/114 reads (46%) | catalogued as rs1472920132; called by muse, mutect2
- MMP16 | c.*7894T>G | 3'UTR (SNP) | VAF 29/72 reads (40%) | called by muse, mutect2, varscan2
- MTMR1 | c.*9-121C>T | Intron (SNP) | VAF 4/39 reads (10%) | called by muse, mutect2, varscan2
- NEO1 | c.*800C>A | 3'UTR (SNP) | VAF 28/42 reads (67%) | called by muse, mutect2, varscan2
- OR4N1P | n.802C>G | RNA (SNP) | VAF 51/265 reads (19%) | called by muse, mutect2, varscan2
- RAB21 | c.391+31A>G | Intron (SNP) | VAF 31/53 reads (58%) | catalogued as COSV54227313; called by muse, mutect2, varscan2
- RAB30 | chr11:82978253 A>G | 3'Flank (SNP) | VAF 100/152 reads (66%) | called by muse, mutect2, varscan2
- RPL5 | c.3+101A>T | Intron (SNP) | VAF 25/204 reads (12%) | called by muse, mutect2, varscan2
- SLCO4C1 | c.*331C>G | 3'UTR (SNP) | VAF 35/67 reads (52%) | called by muse, mutect2, varscan2
- TNRC18P3 | n.1620C>T | RNA (SNP) | VAF 6/13 reads (46%) | catalogued as rs1469413816; called by muse, mutect2, varscan2
- USH2A | c.4627+61T>A | Intron (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- USP3 | c.1097-103A>T | Intron (SNP) | VAF 5/12 reads (42%) | called by muse, varscan2
- USP9X | c.*294A>T | 3'UTR (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2, varscan2
- VTI1B | c.175-69_175-68del | Intron (DEL) | VAF 42/73 reads (58%) | called by mutect2, pindel, varscan2
- ZNF180 | chr19:44473099 C>T | 3'Flank (SNP) | VAF 33/125 reads (26%) | called by muse, mutect2, varscan2
